Somatic mutation profile of tumor specimen TCGA-AA-3971-01A (aliquot TCGA-AA-3971-01A-01W-0995-10) from TCGA case TCGA-AA-3971, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 58.9 years (21,518 days).
Specimen TCGA-AA-3971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00af30f2-7e8a-4552-96ee-f8a0784d0e3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3971-10A (Blood Derived Normal), aliquot TCGA-AA-3971-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c985e606-0be4-4976-89b3-cb5998fb8e73

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 22, Nonsense Mutation 6, Frame Shift Ins 2, RNA 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AAMDC | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as rs144793235; called by muse, mutect2, varscan2
- ADGRG2 | c.1696T>A p.L566I (on ENST00000379869 / NM_001079858.3; = p.L563I on NM_005756.4) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as COSV100491821; called by muse, mutect2, varscan2
- AP4B1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs368828060; called by muse, mutect2, varscan2
- APC | c.1206del p.E403Kfs*51 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV57351508; called by mutect2, pindel
- ARHGEF26 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs1170654348, COSV100726370; called by muse, mutect2, varscan2
- ASB3 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99711699; called by muse, mutect2, varscan2
- CD48 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV100924181, COSV63568021; called by muse, mutect2
- CNGA2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149002674, COSV61704731; called by muse, mutect2, varscan2
- CTR9 | c.1837C>A p.Q613K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV63729917; called by muse, mutect2, varscan2
- DGKI | c.2055G>T p.R685S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV55976986, COSV99932185; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2, varscan2
- DMD | c.4558G>T p.E1520* | Nonsense Mutation (SNP) | VAF 113/172 reads (66%) | catalogued as CM121808, COSV100817466; called by muse, mutect2, varscan2
- DZANK1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99361590; called by muse, mutect2, varscan2
- ECM2 | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1294645375, COSV100755776; called by muse, mutect2
- FAM135B | c.1726C>A p.H576N | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV52755342, COSV99418103; called by muse, mutect2, varscan2
- FZD7 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99636756; called by muse, varscan2
- HDGFL3 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs781730104, COSV55206647; called by muse, mutect2, varscan2
- HOXD12 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV101184101; called by muse, mutect2, varscan2
- IDH3A | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100210707; called by muse, mutect2, varscan2
- IGHM | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs554166742; called by muse, varscan2
- IL18R1 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV99294844; called by muse, varscan2
- ISL1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100044967; called by muse, mutect2, varscan2
- KATNAL1 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs747851515, COSV66065213; called by muse, mutect2, varscan2
- KMT2C | c.10425C>G p.H3475Q | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100065601; called by muse, mutect2, varscan2
- LUZP2 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.024); catalogued as COSV61195482, COSV61221028; called by muse, mutect2, varscan2
- MBD4 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998712; called by muse, mutect2, varscan2
- MYO1A | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1443537148, COSV100270508; called by muse, mutect2, varscan2
- MYO6 | c.2949T>C p.A983= | Splice Region (SNP) | VAF 18/59 reads (31%) | catalogued as COSV64122110; called by muse, mutect2, varscan2
- NSD1 | c.5996T>G p.L1999R | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728352; called by muse, mutect2, varscan2
- NUP188 | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101001157; called by muse, mutect2, varscan2
- NYAP2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55998477; called by muse, mutect2, varscan2
- PABPC5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1386989444, COSV57042189, COSV57043000; called by muse, varscan2
- PCDHA6 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65348324; called by muse, mutect2, varscan2
- PDGFRB | c.2886G>C p.L962F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99940081; called by muse, mutect2, varscan2
- PIGG | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as COSV99573550; called by muse, mutect2, varscan2
- PIPOX | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as rs148923684; called by muse, mutect2, varscan2
- PLEKHH1 | c.3295C>T p.R1099C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs756012004, COSV61284479; called by muse, mutect2, varscan2
- PLXNB1 | c.1378G>C p.D460H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602157; called by muse, mutect2, varscan2
- POLQ | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV51749404, COSV51763648; called by muse, mutect2, varscan2
- PON3 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV55702571; called by muse, mutect2, varscan2
- PRR12 | c.2833C>T p.R945W (on ENST00000615927; = p.R1766W on NM_020719.3) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101330542; called by muse, mutect2, varscan2
- PRTG | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.863); catalogued as COSV101221212; called by muse, mutect2, varscan2
- PWP1 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101338780; called by muse, mutect2, varscan2
- SCN11A | c.4855G>A p.G1619S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56568167, COSV56580195; called by muse, mutect2, varscan2
- SIRPB2 | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100708363; called by muse, mutect2, varscan2
- SNIP1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56165679, COSV99952947; called by muse, mutect2
- SORBS1 | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs772386830, COSV53367631; called by muse, mutect2, varscan2
- SPRED1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs749378713, COSV54435158; called by muse, mutect2, varscan2
- SRCIN1 | c.676C>T p.R226W (on ENST00000621492; = p.R192W on NM_025248.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs774129976; called by muse, mutect2, varscan2
- SSTR1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99942662; called by muse, mutect2
- TDRD3 | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs903398878, COSV99539692; called by muse, mutect2, varscan2
- TENM4 | c.6167G>T p.R2056L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99570295; called by muse, mutect2, varscan2
- TLR3 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs780744847, COSV99710784; called by muse, mutect2, varscan2
- TM4SF19 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV56556690, COSV99879252; called by muse, mutect2, varscan2
- TMOD1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs771595062, COSV99403692; called by muse, mutect2, varscan2
- TTC17 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 162/351 reads (46%) | catalogued as COSV50025346, COSV99236078; called by muse, mutect2, varscan2
- TTN | c.100483C>T p.R33495W (on ENST00000591111; = p.R26071W on NM_003319.4) | Missense Mutation (SNP) | VAF 125/824 reads (15%) | PolyPhen possibly damaging (0.862); catalogued as rs372875128, COSV100592100; ClinVar: benign / uncertain significance / likely benign; called by muse, varscan2
- UGT2A3 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV99279548; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3820dup p.L1274Pfs*16 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs1444457394; called by pindel, varscan2
- UNC13C | c.3488A>C p.K1163T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as rs1344985620, COSV52893612, COSV99510930; called by muse, mutect2, varscan2
- VCAN | c.9889G>A p.G3297S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1338387651, COSV54120428; called by muse, mutect2, varscan2
- WSCD2 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs777932595, COSV99045889, COSV99773982; called by muse, varscan2
- ZNF410 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57912626; called by muse, mutect2, varscan2
- APOBR | c.1634T>C p.L545P (on ENST00000431282; = p.L554P on NM_018690.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- DOC2A | c.268_271dup p.G91Afs*7 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- OR8B3 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- AICDA | c.231C>T p.R77= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs754343795, COSV57563679; called by muse, mutect2, varscan2
- ANK2 | c.873G>A p.Q291= | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as COSV99999276; called by muse, mutect2, varscan2
- BBS4 | c.138A>G p.K46= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as COSV99166379; called by muse, mutect2
- COL3A1 | c.1786C>A p.R596= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as CM1412533, COSV58590658, COSV58598276; called by muse, mutect2, varscan2
- DMRT3 | c.597C>T p.S199= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs539407759, COSV51903655; called by muse, varscan2
- KRT78 | c.639C>T p.N213= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs148650209; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1095C>T p.T365= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1555928905, COSV100169962; called by muse, varscan2
- MACC1 | c.444C>T p.D148= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as rs765810351, COSV100255091; called by muse, mutect2, varscan2
- MBD5 | c.2982G>A p.A994= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs572893308, COSV68699278; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTUS2 | c.1071C>T p.T357= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs372153145; called by muse, mutect2, varscan2
- MYOF | c.78C>A p.V26= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV63712037; called by muse, mutect2, varscan2
- NCAM2 | c.729C>T p.S243= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV53109208; called by muse, mutect2, varscan2
- NSD1 | c.5997C>T p.L1999= | Silent (SNP) | VAF 155/350 reads (44%) | catalogued as rs562617982, COSV100728355; called by muse, mutect2, varscan2
- NT5C3B | c.198C>T p.S66= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV53175490; called by muse, mutect2, varscan2
- RBM26 | c.1080C>T p.L360= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs371673779; called by muse, mutect2, varscan2
- SAMD15 | c.279A>G p.R93= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99374731; called by muse, mutect2, varscan2
- SCN9A | c.5484G>A p.L1828= (on ENST00000303354; = p.L1817= on NM_002977.3) | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV57628557; called by muse, mutect2, varscan2
- SERPINB4 | c.1041C>T p.T347= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs754500172, COSV61986502; called by muse, mutect2, varscan2
- TRIM42 | c.633C>T p.H211= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1475368922, COSV53881710; called by muse, mutect2, varscan2
- TTN | c.66444C>T p.T22148= (on ENST00000591111; = p.T14724= on NM_003319.4) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV60159850; called by muse, mutect2, varscan2
- WDR91 | c.1527T>C p.S509= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- WNK3 | c.2427T>C p.A809= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV63616359; called by muse, mutect2, varscan2
- HERC2P3 | n.485T>A | RNA (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- TMEM99 | n.539T>A | RNA (SNP) | VAF 111/445 reads (25%) | catalogued as COSV56986080; called by muse, mutect2, varscan2
